Somatic mutation profile of tumor specimen MP2PRT-PAUDGG-TMP1-A (aliquot MP2PRT-PAUDGG-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUDGG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (635 days).
Specimen MP2PRT-PAUDGG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf796c69-2c92-4c83-af66-95e261530f78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDGG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDGG-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48289e53-7793-4908-a156-5bdf2dd059fe

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX30 | c.762G>C p.Q254H (on ENST00000445061 / NM_138615.3; = p.Q215H on NM_014966.3) | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100820063; called by muse, mutect2
- DIAPH2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs757562335; called by muse, mutect2, varscan2
- TTN | c.38732C>T p.S12911L (on ENST00000591111; = p.S5487L on NM_003319.4) | Missense Mutation (SNP) | VAF 31/287 reads (11%) | PolyPhen benign (0.08); catalogued as rs1454698596, COSV59958416, COSV60150059; called by muse, mutect2, varscan2
- CATSPER1 | c.1585A>T p.M529L | Missense Mutation (SNP) | VAF 226/524 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592654 ACAATGGCCTCCCCTCACTGTGTCTC>GGA | Missense Mutation (DEL) | VAF 35/105 reads (33%) | called by pindel, varscan2*
- RAB11FIP2 | c.574C>G p.H192D | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.127); called by muse, mutect2
- RP1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 76/841 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNBD1 | c.162G>A p.R54= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV101572853; called by muse, mutect2, varscan2
- DNAH14 | c.6033+2174G>A | Intron (SNP) | VAF 19/299 reads (6%) | catalogued as rs1033765753; called by muse, mutect2
